TCGA case TCGA-EK-A2RN — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b610d391-0c9d-4114-94d6-5e4aa4270122

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 45.1 years (16,487 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 15; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS.

Follow-up (2 entries)
- Day 0 (preoperative): ECOG performance status: 0.
- Days to follow up: 71 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 176 cm; BMI: 22.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 60 mg.
  Slide TCGA-EK-A2RN-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2RN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 0; Pregnancies count induced abortion: 1; Total pregnancy count: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Cone Biopsy / LEEP; Margins involved hysterectomy: Other Location, specify; Other involved margins: parametrial involvement on the right side only; Lymph nodes examined: Yes; Lymphovascular invasion: Present.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 71 days; disease-specific survival: no event (censored), 71 days; progression-free interval: no event (censored), 71 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2RN-01A-12D-A20T-01): tumor purity 0.63, ploidy 2.95, whole-genome doublings 1.
